Gene-level copy-number profile of tumor specimen TCGA-WP-A9GB-01A from TCGA case TCGA-WP-A9GB, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Myometrium.
Specimen TCGA-WP-A9GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.6d98506f-9d10-47d5-8fed-4e11cec0bad2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WP-A9GB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4a50bf8-11dd-4509-8d8a-bd488eae7fd3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 2,201; copy number 2: 17,347; copy number 3: 17,458; copy number 4: 18,530; copy number 5: 3,551; copy number 6: 474; copy number 7: 129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WP-A9GB-01A-11D-A37B-01): tumor purity 0.97, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,623,190–3,796,498, 13 genes: AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27, SMIM1, LRRC47, RN7SL574P, AL365330.1.
- chr1:232,160,091–233,295,725, 14 genes (within-gene range 0–2): AL353052.1, AL353052.2, BX323014.1, RN7SL299P, SIPA1L2, RNU6-1211P, LINC01745, LINC01744, MAP10, RNU1-74P, AL122003.2, AL122003.1, NTPCR, PCNX2.
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr5:68,087,161–68,565,515, 9 genes: AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2, AC010280.1, AC010280.3.
- chr10:44,712–689,668, 10 genes (within-gene range 0–1): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1.
- chr10:29,711,915–29,891,467, 2 genes: RNU6-908P, AL353093.1.
- chr13:48,232,612–51,080,862, 65 genes (broad region; genes not listed).
- chr21:46,635,595–46,665,124, 2 genes: PRMT2, DSTNP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
